TCGA case TCGA-FB-AAQ1 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ff8dac97-42ff-4f48-81c4-50315ad8de58

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Dead; Days to death: 123 days; Cause of death source: Medical Record.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 49.8 years (18,172 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 123 days; Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 27; Tumor largest dimension diameter: 6 cm.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 123 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2005.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FB-AAQ1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 660 mg.
  Slide TCGA-FB-AAQ1-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FB-AAQ1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FB-AAQ1-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,030 mg.
  Slide TCGA-FB-AAQ1-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Alcohol history documented: No; Diabetes diagnosis indicator: No; History chronic pancreatitis: No; Treatment outcome first course: Stable Disease.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Stable Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Partial Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 123 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 123 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 123 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FB-AAQ1-01A-12D-A40V-01): tumor purity 0.24, ploidy 3.35, whole-genome doublings 1.
